Gene-level copy-number profile of tumor specimen TARGET-10-PATWYL-09A from TARGET case TARGET-10-PATWYL, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.3 years (5,586 days).
Specimen TARGET-10-PATWYL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d39ff0d9-8fb6-544c-9b4a-fe82c83dac49.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATWYL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 369 have no estimate.
https://portal.gdc.cancer.gov/files/f35a49f3-1d5d-4f3e-87ec-cf7494c79a05

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 92; copy number 1: 3,019; copy number 2: 56,597; copy number 3: 357; copy number 4: 131; copy number 5: 54; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,322,730, 11 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA.
- chr9:11,275,314–11,276,314, 1 gene: AL451129.1.
- chr9:21,966,929–22,128,103, 8 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr14:21,962,819–22,499,749, 70 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 2–5): AC244205.1.
- chr2:88,857,161–89,254,015, 40 genes, copy number 5: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr4:68,537,184–68,628,899, 4 genes, copy number 6 (within-gene range 2–6): UGT2B17, AC147055.2, AC147055.4, AC147055.3.
- chr13:90,890,954–91,354,579, 12 genes, copy number 5: LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr13:91,485,793–91,486,870, 1 gene, copy number 5: AL356118.1.

Autosomal genes at a single copy (total copy number 1): 634. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
